Somatic mutation profile of tumor specimen 0DDC9I from CCDI case PBBLKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,824 days).
Specimen 0DDC9I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a19ac5c1-5cb0-49da-98d5-ec227828dbe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDC9J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fc50c28-d54a-4d62-bef9-decb8107b9d9

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, 3'UTR 1, Missense Mutation 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LGI3 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 83/334 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.048); catalogued as rs760988110; called by muse, mutect2, varscan2
- SLITRK6 | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 113/388 reads (29%) | called by muse, mutect2, varscan2
- BRCC3 | c.948A>G p.E316= | Silent (SNP) | VAF 44/250 reads (18%) | called by muse, mutect2, varscan2
- AUTS2 | c.2005-92C>T | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as rs529972118; called by mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 38/280 reads (14%) | called by muse, varscan2
